TARGET case TARGET-00-BM4404 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ad577f18-292c-40c7-9ecb-a8b73b6e1d8a

Biospecimens (1 sample)
- Sample TARGET-00-BM4404-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
